Somatic mutation profile of tumor specimen TCGA-ZB-A96B-01A (aliquot TCGA-ZB-A96B-01A-11D-A428-09) from TCGA case TCGA-ZB-A96B, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type B1, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 51.7 years (18,892 days).
Specimen TCGA-ZB-A96B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c779193b-a8bf-465e-8ce7-e59e669f1eeb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZB-A96B-10A (Blood Derived Normal), aliquot TCGA-ZB-A96B-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5919bda-91ca-4cc2-a471-d6083ad579bd

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 22/572 reads (4%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2
- TTC8 | c.1024G>T p.V342L (on ENST00000338104 / NM_001288781.1; = p.V326L on NM_144596.4) | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as rs1276008245, COSV57627669; called by muse, mutect2
- ABCG8 | c.1490T>C p.I497T | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2
- KCNAB2 | c.779C>A p.P260Q | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.499); called by muse, mutect2
- POTEE | c.2534C>A p.S845Y | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RYR2 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.344); called by muse, mutect2
- TAP1 | c.382C>A p.L128I | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- PCLO | c.6285C>A p.T2095= | Silent (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2
